Surgical pathology report (de-identified scan), TCGA case TCGA-IR-A3LB, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-IR-A3LB-01A (Primary Tumor).

[page 1 of 2]
Specimens Submitted:

- 1: SP: Left lower common iliac lymph nodes (fs)
- 2: SP: Right para-aortic nodes (fs)
- 3: SP: Left para-aortic lymph nodes (fs)
- 4: SP: Radical trialectomy w/ bilateral adnexae
- 5: SP: Left external iliac lymph nodes
- 6: SP: Left obturator lymph node
- 7: SP: Left hypogastric lymph nodes
- 8: SP: Right external iliac lymph nodes
- 9: SP: Right common iliac lymph nodes
- 10: SP: Right obturator lymph node
- 11: SP: Right hypogastric lymph node
- 12: SP: Portion of omentum

DIAGNOSIS:

- 1) LYMPH NODE, COMMON ILIAC, LEFT; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 2) LYMPH NODES, PARA-AORTIC, RIGHT; EXCISION:
- THREE BENIGN LYMPH NODES (0/3).
- 3) LYMPH NODES, PARA-AORTIC, LEFT; EXCISION:
- FOUR BENIGN LYMPH NODES (0/4).
- 4) RADICAL TRIALECTOMY WITH BILATERAL ADNEXAE; RESECTION:
- INVASIVE ADENOCARCINOMA OF UTERINE CERVIX, NOS, WITH MODERATELY AND POORLY DIFFERENTIATED COMPONENTS.
- THE MAXIMAL THICKNESS OF THE CERVICAL STROMAL INVASION IS 18 MM.
- THE THICKNESS OF THE CERVIX IN THE AREA OF MAXIMAL TUMOR INVASION IS 20 MM.
- TUMOR EXTENDS INTO PERICERVICAL SOFT TISSUE.
- VASCULAR INVASION IS PRESENT.
- PERINEURAL INVASION IS PRESENT.
- NO VAGINAL EXTENSION IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE RIGHT OVARY SHOWS A CYSTADENOFIBROMA.

PATH
REPORT

** Continued on next page **

1CD-0-3

adenocarcinoma, endocervical type 8384/3
Site: cervix, NOS C53.9 lw 12/21/11

Per review by pathologist at TSS - Endocervical Type.

[page 2 of 2]
[REDACTED]

- ALL OTHER ADNEXAE ARE UNREMARKABLE.

- 5) LYMPH NODES, EXTERNAL ILIAC; EXCISION:
- SIX BENIGN LYMPH NODES (0/6).
- 6) LYMPH NODES, OBTURATOR, LEFT; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 7) LYMPH NODE, HYPOGASTRIC, LEFT; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 8) LYMPH NODE, EXTERNAL ILIAC, RIGHT; EXCISION:
- SEVEN BENIGN LYMPH NODES (0/7).
- 9) LYMPH NODES, COMMON ILIAC, RIGHT; EXCISION:
- THREE BENIGN LYMPH NODES (0/3).
- 10) LYMPH NODES, OBTURATOR, RIGHT; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 11) LYMPH NODE, HYPOGASTRIC, RIGHT; EXCISION:
- BENIGN VASCULAR AND ADIPOSE TISSUE.
- 12) OMENTUM; BIOPSY:
- BENIGN ADIPOSE TISSUE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[REDACTED]

*** Report Electronically Signed Out *** [REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 0df1716c-271e-4700-b75a-33cecfc56430 (TCGA-IR-A3LB.8E99E100-EB4F-472A-BB28-36592B1AA26E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).